CCDI case PBBSEW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/15160f7b-5317-4931-b0ee-e15b2beef1d8

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 12.9 years (4,715 days).

Biospecimens (3 samples)
- Sample 0DGYZ4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGZAA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGZFD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
